Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25V, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25V-01A (Primary Tumor).

[page 1 of 2]
Laboratory Services

ICD-0-3
carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 lw 4/25/11

MRN:
PHN:
ACB:
DOB/Gender:
Telephone:
Encounter:

Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Received Date/Time:

Specimen Description

- A. Gallbladder - FS
- B. Liver segment 5

Clinical Information

Liver mass which looks like hepatocellular carcinoma; patient has known cirrhosis secondary to alcohol ingestion. Liver Ca.

Diagnosis

- A. Gallbladder:
- Chronic cholecystitis
- B. Liver Segment 5:
- Moderately-differentiated hepatocellular carcinoma, 1.5 cm in the greatest dimension. Resection margins are free of tumor.
- Cirrhosis

ICDPA Discrepancy		X

Cc:

[page 2 of 2]
Surgical Pathology Report

Inquiry Numbers:

Received Date/Time:

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name [REDACTED], [REDACTED]. The cassettes and AP identifiers are labelled with the Surgical Number

A. The specimen consists of a gallbladder measuring 10.0 x 3.5 x 1.2 cm. The gallbladder is filled with yellow-greenish bile without stones. The mucosa is velvety and granular. There is no tumor identified. AgNO3. One random section taken for QS.

Three further representative sections of the specimen are submitted in cassette A2.

B. The specimen is received fresh and is subsequently placed into formalin and consists of a congested wedge of liver weighing 17.9 grams and measuring 4.0 x 3.0 x 3.0 cm. The resection margin is inked blue. Specimen is sectioned and the liver parenchyma grossly appears to be cirrhotic. Within the specimen is a yellow/tan circumscribed lesion measuring 1.5 x 1.5 x 1.0 cm. Grossly, this lesion comes within 0.6 cm of the blue-painted margin and 0.2 cm through the capsule. The mass is submitted in toto in cassettes B1 to B4. Further representative sections of liver are submitted in cassette B5.

Frozen Section Diagnosis

A. Gallbladder:
- Negative for malignancy

Cc:

Pathology: Provider - Permanent
Page 2 of 2

Source: NCI Genomic Data Commons file c2ef6a29-61b7-4c39-b7c8-e0f0f6002001 (TCGA-G3-A25V.F52224B9-1FAF-4F71-B017-22AAEBA8F75D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).